Somatic mutation profile of tumor specimen C3L-09390-04 (aliquot CPT0538950009) from CPTAC case C3L-09390, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 81.6 years (29,808 days).
Specimen C3L-09390-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd4cb898-4fd6-4d77-8b5b-174f9ebb4df6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09390-31 (Blood Derived Normal), aliquot CPT0539070004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47ebed7e-d715-4cd3-8b1d-8d9bb194951e

The open-access MAF lists 81 somatic variants for this specimen: 54 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 25, Nonsense Mutation 4, Frame Shift Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757210054; called by muse, mutect2
- ANKDD1A | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs144050562; called by muse, mutect2
- ANKRD30A | c.3503T>G p.L1168R (on ENST00000611781; = p.L1112R on NM_052997.2) | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64610320; called by muse, mutect2
- CD5L | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.688); catalogued as rs201351165; called by muse, mutect2
- EHD3 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 25/397 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs138007410; called by muse, mutect2
- ELF1 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.735); catalogued as rs1202088721, COSV53501278; called by muse, mutect2
- FASLG | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs763787856; called by muse, mutect2, varscan2
- HSPA2 | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 16/411 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs1254979247; called by muse, mutect2
- IGHA2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs573262638; called by muse, mutect2
- IL1RL1 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs756672386; called by muse, mutect2
- IQSEC3 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 41/558 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs782459662; called by muse, mutect2
- KLHL38 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373548260; called by muse, mutect2
- MED25 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 38/495 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as rs1340131942; called by muse, mutect2
- MRTFA | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs201635580, COSV62933226; called by muse, mutect2
- MUC4 | c.5585C>T p.A1862V | Missense Mutation (SNP) | VAF 34/1090 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as rs748313278; called by muse, mutect2
- OR11H1 | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV53271168; called by muse, mutect2
- OR6T1 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 35/422 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.53); catalogued as rs762711758; called by muse, mutect2
- PCDHA13 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 21/582 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs782795158; called by muse, mutect2
- RASAL2 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT tolerated (0.89); PolyPhen benign (0.145); catalogued as COSV62714389; called by muse, mutect2
- SCN1A | c.5797C>T p.R1933* (on ENST00000303395 / NM_001202435.3; = p.R1922* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/230 reads (17%) | catalogued as rs1351809843, COSV57662795; called by muse, mutect2, varscan2
- SIMC1 | c.757C>T p.R253W (on ENST00000443967 / NM_001308196.1; = p.R272W on NM_001308195.2) | Missense Mutation (SNP) | VAF 45/534 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as rs756201624, COSV57904129; called by muse, mutect2
- SPATA31D1 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 24/562 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV100782455, COSV61194759; called by muse, mutect2
- TCOF1 | c.4336G>A p.D1446N (on ENST00000377797 / NM_001135243.1; = p.D1369N on NM_000356.4) | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1405299412; called by muse, mutect2, varscan2
- TRPV5 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.45); catalogued as rs748976874; called by muse, mutect2
- TWIST2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 50/517 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1478480116, COSV71820868; called by muse, mutect2, varscan2
- USH2A | c.3471C>G p.I1157M | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV100227919; called by muse, mutect2
- ZNF578 | c.1324C>A p.L442I | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV69737749; called by muse, mutect2
- ABCC9 | c.2558A>G p.E853G | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2
- AMELX | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- CADPS | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CLEC3A | c.148G>T p.D50Y (on ENST00000651443; = p.D41Y on NM_005752.6) | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- DCAF12L1 | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.265); called by muse, mutect2
- DNAH7 | c.5101G>A p.E1701K | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELN | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FAM170A | c.698G>A p.C233Y | Missense Mutation (SNP) | VAF 33/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO41 | c.296C>A p.S99* | Nonsense Mutation (SNP) | VAF 17/432 reads (4%) | called by muse, mutect2
- GPR6 | c.1044C>A p.F348L | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- GRIA2 | c.2478G>T p.L826F | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LCP1 | c.1262C>A p.S421* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- LIPF | c.285del p.N96Tfs*63 | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by mutect2, pindel
- MALRD1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2
- MMP1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOD2 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); called by muse, mutect2
- PDE1A | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 15/308 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PTPN14 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2
- SCD5 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 20/269 reads (7%) | called by muse, mutect2
- SCN10A | c.5125T>C p.S1709P | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SCN9A | c.2765G>A p.R922H (on ENST00000303354; = p.R911H on NM_002977.3) | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TET3 | c.5206G>A p.E1736K | Missense Mutation (SNP) | VAF 18/542 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2
- TOPAZ1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- TRIM10 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 72/733 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- USF2 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 20/459 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- USP20 | c.2516C>T p.P839L | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); called by muse, mutect2
- ZNF865 | c.2612C>T p.T871M | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2
- ASCL4 | c.96G>A p.P32= | Silent (SNP) | VAF 17/472 reads (4%) | catalogued as COSV100661223; called by muse, mutect2
- ATP6V0B | c.516C>G p.L172= | Silent (SNP) | VAF 42/566 reads (7%) | catalogued as COSV52543400; called by muse, mutect2
- CASR | c.60C>T p.Y20= | Silent (SNP) | VAF 29/364 reads (8%) | catalogued as rs201564143, CM123738; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2
- CFAP47 | c.6654G>A p.T2218= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- COX17 | c.58C>T p.L20= | Silent (SNP) | VAF 10/265 reads (4%) | called by muse, mutect2
- GCFC2 | c.96G>C p.P32= | Silent (SNP) | VAF 22/430 reads (5%) | catalogued as COSV58083329; called by muse, mutect2
- GGTLC1 | c.48C>T p.D16= | Silent (SNP) | VAF 37/536 reads (7%) | catalogued as rs748582298, COSV53849565; called by muse, mutect2
- GPLD1 | c.1428C>T p.S476= | Silent (SNP) | VAF 18/205 reads (9%) | catalogued as rs140374151; called by muse, mutect2, varscan2
- HS3ST2 | c.258C>A p.P86= | Silent (SNP) | VAF 16/494 reads (3%) | called by muse, mutect2
- KNDC1 | c.4173G>A p.E1391= | Silent (SNP) | VAF 50/532 reads (9%) | called by muse, mutect2
- MAGEB4 | c.687C>A p.I229= | Silent (SNP) | VAF 26/323 reads (8%) | called by muse, mutect2
- MMP2 | c.87C>T p.A29= | Silent (SNP) | VAF 37/456 reads (8%) | catalogued as rs1342572491; called by muse, mutect2
- PCLO | c.11070C>T p.D3690= | Silent (SNP) | VAF 20/316 reads (6%) | catalogued as rs200715895, COSV61657640; called by muse, mutect2
- PRKCH | c.1494C>T p.F498= | Silent (SNP) | VAF 29/322 reads (9%) | catalogued as rs781476928, COSV60646845; called by muse, mutect2
- SAMD15 | c.318G>A p.E106= | Silent (SNP) | VAF 18/380 reads (5%) | called by muse, mutect2
- SLC12A4 | c.2220C>T p.G740= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as rs567542501; called by muse, mutect2
- SORCS1 | c.2532T>G p.S844= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as rs1168328047, COSV99550925; called by muse, mutect2
- SPEM3 | c.1779G>A p.P593= | Silent (SNP) | VAF 22/335 reads (7%) | catalogued as rs1042637838, COSV60071688; called by muse, mutect2
- SS18L1 | c.855C>G p.S285= | Silent (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- SYCP2L | c.1467C>T p.V489= | Silent (SNP) | VAF 18/326 reads (6%) | catalogued as rs1462853995, COSV99304813; called by muse, mutect2
- TRPM3 | c.3888C>T p.A1296= (on ENST00000357533 / NM_001366142.2; = p.A1151= on NM_020952.6) | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as rs989267933, COSV62583675; called by muse, mutect2
- TUBA3C | c.1266C>T p.R422= | Silent (SNP) | VAF 28/489 reads (6%) | catalogued as rs141224369; called by muse, mutect2
- UTP14A | c.2304C>T p.C768= | Silent (SNP) | VAF 39/145 reads (27%) | called by muse, mutect2, varscan2
- ZFYVE27 | c.843T>C p.A281= | Silent (SNP) | VAF 22/294 reads (7%) | called by muse, mutect2
- ZNF775 | c.1437C>T p.C479= | Silent (SNP) | VAF 38/505 reads (8%) | catalogued as rs1484567615; called by muse, mutect2
- ATXN8OS | n.349A>T | RNA (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- FARP1 | c.1414+932G>A | Intron (SNP) | VAF 20/480 reads (4%) | called by muse, mutect2
